Somatic mutation profile of tumor specimen MMRF_2151_1_BM_CD138pos (aliquot MMRF_2151_1_BM_CD138pos_T1_KHS5U_L08658) from MMRF case MMRF_2151, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.7 years (20,712 days).
Specimen MMRF_2151_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1f6ad86-5614-4cf3-8c35-5989000288cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2151_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2151_1_PB_Whole_C2_KHS5U_L08659; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9467963-3635-4faf-b2e3-8ba8fc404c62

The open-access MAF lists 90 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 27, Silent 10, Intron 5, 5'UTR 3, 3'Flank 3, Nonsense Mutation 3, Splice Region 3, RNA 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- API5 | c.354C>A p.N118K | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1424472579; called by muse, mutect2, varscan2
- C4orf54 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs1280854125; called by muse, mutect2, varscan2
- CFHR2 | c.467A>G p.D156G | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as rs764374666; called by muse, mutect2
- CNTD1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1339765228, COSV99889438; called by muse, mutect2, varscan2
- CYP27C1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 61/108 reads (56%) | catalogued as COSV58866180; called by muse, mutect2, varscan2
- DLGAP2 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs949370630, COSV70100249; called by muse, mutect2, varscan2
- H3C8 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 50/852 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV59953904; called by muse, mutect2
- HOOK1 | c.1051A>G p.M351V | Missense Mutation (SNP) | VAF 160/352 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs780038764; called by muse, varscan2
- PTCHD1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 120/122 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1170731709; called by muse, mutect2, varscan2
- SCN3B | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 20/409 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1232088805; called by muse, mutect2
- SEMA5A | c.1291A>G p.K431E | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472416735; called by muse, mutect2, varscan2
- ZNF235 | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 162/355 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs757174119; called by muse, mutect2, varscan2
- ZNF292 | c.6393G>C p.L2131F | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100370229; called by muse, mutect2
- ZNF384 | c.1184G>A p.R395Q (on ENST00000361959; = p.R334Q on NM_133476.5) | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1344310148; called by muse, mutect2, varscan2
- AFF1 | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2
- CACNA1B | c.5346C>G p.I1782M | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- CARF | c.797A>C p.Y266S | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYLC2 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPHB3 | c.1458C>A p.Y486* | Nonsense Mutation (SNP) | VAF 135/529 reads (26%) | called by muse, mutect2, varscan2
- FGFR1 | c.1580A>G p.D527G (on ENST00000447712 / NM_023110.3; = p.D525G on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/313 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFI1B | c.578C>G p.A193G | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- GNA12 | c.697T>A p.S233T | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.146); called by muse, varscan2
- KCNK2 | c.598T>C p.F200L (on ENST00000444842 / NM_001017425.3; = p.F185L on NM_014217.4) | Missense Mutation (SNP) | VAF 395/827 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLK3 | c.630+7C>T | Splice Region (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- LRRC53 | c.3676G>C p.A1226P | Missense Mutation (SNP) | VAF 130/289 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MKRN2 | c.1113+6G>C | Splice Region (SNP) | VAF 74/239 reads (31%) | called by muse, mutect2, varscan2
- MTMR6 | c.555A>T p.R185S | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKD1 | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NKX2-2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR2AG1 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 89/605 reads (15%) | called by muse, mutect2, varscan2
- OXR1 | c.1880G>A p.G627E (on ENST00000442977 / NM_001198532.1; = p.G626E on NM_018002.3) | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHA6 | c.2855A>C p.E952A | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RGS20 | c.569C>A p.T190K (on ENST00000297313 / NM_170587.4; = p.T43K on NM_003702.4) | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RIMS1 | c.3396A>G p.E1132= | Splice Region (SNP) | VAF 68/79 reads (86%) | called by muse, mutect2, varscan2
- SMAD7 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 143/274 reads (52%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SVIL | c.1175G>C p.S392T | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- TPP2 | c.3575A>T p.N1192I | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated (0.39); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADAMTS18 | c.345G>A p.S115= | Silent (SNP) | VAF 130/258 reads (50%) | catalogued as rs779800493; called by muse, mutect2, varscan2
- C18orf25 | c.1056G>A p.Q352= | Silent (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- CCDC91 | c.1026A>C p.T342= | Silent (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- CLDN4 | c.210G>T p.L70= | Silent (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- COL4A4 | c.2790C>T p.G930= | Silent (SNP) | VAF 87/161 reads (54%) | catalogued as rs768448299, COSV100306519; called by muse, mutect2, varscan2
- FAM13A | c.2130T>C p.N710= | Silent (SNP) | VAF 30/370 reads (8%) | called by muse, mutect2
- FMO1 | c.141T>G p.V47= | Silent (SNP) | VAF 144/356 reads (40%) | called by muse, mutect2, varscan2
- IRF2BPL | c.1674G>A p.L558= | Silent (SNP) | VAF 93/99 reads (94%) | catalogued as rs979663769; called by muse, mutect2, varscan2
- PLXNB2 | c.1117C>T p.L373= | Silent (SNP) | VAF 80/175 reads (46%) | called by muse, mutect2, varscan2
- SLC39A4 | c.516G>A p.G172= (on ENST00000301305 / NM_001374839.1; = p.G147= on NM_017767.3) | Silent (SNP) | VAF 63/67 reads (94%) | catalogued as rs1554873623; called by muse, mutect2, varscan2
- ATP2B2 | chr3:10324109 C>T | 3'Flank (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*483G>T | 3'UTR (SNP) | VAF 67/128 reads (52%) | called by muse, mutect2, varscan2
- BOLA1 | c.-634G>A | 5'UTR (SNP) | VAF 13/115 reads (11%) | catalogued as rs782466280; called by muse, mutect2, varscan2
- BTBD3 | c.*1317T>G | 3'UTR (SNP) | VAF 62/143 reads (43%) | called by muse, mutect2, varscan2
- CCDC69 | c.-85G>A | 5'UTR (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- CCL4 | c.192-129C>G | Intron (SNP) | VAF 15/232 reads (6%) | catalogued as rs752434908; called by muse, mutect2
- CHAT | c.*15T>A | 3'UTR (SNP) | VAF 179/794 reads (23%) | called by muse, mutect2, varscan2
- CLOCK | c.*1274G>A | 3'UTR (SNP) | VAF 58/154 reads (38%) | called by muse, mutect2, varscan2
- CXCL13 | c.*784C>A | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- DHTKD1 | c.*357A>C | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by mutect2, varscan2
- DNAJC5 | c.*3053C>T | 3'UTR (SNP) | VAF 11/206 reads (5%) | called by muse, mutect2
- DST | c.4297-2263A>T | Intron (SNP) | VAF 213/221 reads (96%) | called by muse, mutect2, varscan2
- ELP2 | chr18:36129884 C>A | 5'Flank (SNP) | VAF 121/567 reads (21%) | called by muse, mutect2, varscan2
- FKBP15 | c.324+48A>G | Intron (SNP) | VAF 82/258 reads (32%) | called by muse, mutect2, varscan2
- GALK2 | c.*391G>A | 3'UTR (SNP) | VAF 240/762 reads (31%) | catalogued as rs753592849; called by muse, varscan2
- GJD2 | c.-295G>T | 5'UTR (SNP) | VAF 52/202 reads (26%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1085-391G>A | Intron (SNP) | VAF 57/175 reads (33%) | catalogued as rs1338315573; called by muse, mutect2, varscan2
- GUCY1A1 | c.*1719G>C | 3'UTR (SNP) | VAF 84/186 reads (45%) | called by muse, mutect2, varscan2
- HCAR1 | c.*983G>A | 3'UTR (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- KANSL3 | c.*98G>A | 3'UTR (SNP) | VAF 37/249 reads (15%) | catalogued as rs1301486826; called by muse, mutect2, varscan2
- LHX4 | c.*2668T>A | 3'UTR (SNP) | VAF 104/179 reads (58%) | called by muse, mutect2, varscan2
- LINC01553 | n.1909T>G | RNA (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- LRRC58 | c.*2340A>G | 3'UTR (SNP) | VAF 38/277 reads (14%) | catalogued as rs751140566; called by muse, mutect2, varscan2
- MBL2 | c.*1776G>A | 3'UTR (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- MS4A3 | c.*850T>C | 3'UTR (SNP) | VAF 7/194 reads (4%) | called by muse, mutect2
- NAGA | c.*1903C>G | 3'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- ODF2L | c.*237dup | 3'UTR (INS) | VAF 78/180 reads (43%) | catalogued as rs923727542; called by mutect2, varscan2
- PCDH15 | c.*2337A>C | 3'UTR (SNP) | VAF 51/104 reads (49%) | called by muse, mutect2, varscan2
- PPM1H | c.*3946C>G | 3'UTR (SNP) | VAF 44/77 reads (57%) | called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3474C>T | RNA (SNP) | VAF 50/92 reads (54%) | catalogued as rs544625193; called by muse, varscan2
- RAB18 | c.*277T>A | 3'UTR (SNP) | VAF 34/76 reads (45%) | catalogued as rs552999694; called by muse, mutect2, varscan2
- RARRES2P7 | n.46C>T | RNA (SNP) | VAF 68/164 reads (41%) | catalogued as rs1374122821; called by muse, mutect2, varscan2
- RNF20 | c.*20A>G | 3'UTR (SNP) | VAF 132/430 reads (31%) | called by muse, mutect2, varscan2
- SDC4 | c.*1627del | 3'UTR (DEL) | VAF 20/190 reads (11%) | catalogued as rs1388120364; called by pindel, varscan2*
- SENP2 | chr3:185582497 T>A | 5'Flank (SNP) | VAF 94/673 reads (14%) | called by muse, mutect2, varscan2
- SH3GLB2 | c.335-926del | Intron (DEL) | VAF 28/42 reads (67%) | called by mutect2, varscan2
- SLC38A2 | c.*897T>A | 3'UTR (SNP) | VAF 92/174 reads (53%) | called by muse, mutect2, varscan2
- SMIM13 | chr6:11138392 C>A | 3'Flank (SNP) | VAF 69/227 reads (30%) | called by muse, mutect2, varscan2
- STX6 | c.*2875A>G | 3'UTR (SNP) | VAF 60/141 reads (43%) | catalogued as rs746224433; called by muse, mutect2, varscan2
- SYNPR | c.*1020G>C | 3'UTR (SNP) | VAF 69/222 reads (31%) | called by muse, mutect2, varscan2
- TGFBRAP1 | chr2:105266941 C>A | 3'Flank (SNP) | VAF 111/268 reads (41%) | called by muse, mutect2, varscan2
- TLCD4 | c.*207T>C | 3'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- UNC5D | c.*4849C>T | 3'UTR (SNP) | VAF 89/184 reads (48%) | catalogued as rs997496207; called by muse, mutect2, varscan2
